Surgical pathology report (de-identified scan), TCGA case TCGA-56-A4BX, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-A4BX-01A (Primary Tumor).

MRN #:
Ref Physician:

SPECIMEN INFO

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Lung, right lower lobe, excision:

Tumor Characteristics:

1. Histologic type: Squamous cell carcinoma.
2. Histologic grade: Grade II, moderately differentiated
3. Tumor site: Right lower lobe.
4. Tumor focality: Unifocal.
5. Tumor size: 6.0 x 5.0 x 3.5 cm.
6. Visceral pleural invasion: Not identified.
7. Lymphovascular space invasion: Not identified.
8. Tumor extension: Tumor confined to lung parenchyma.

Surgical Margin Status:

1. Tumor distance from bronchial margin: 4.5 cm.
2. Tumor distance from parenchymal (stapled) margin: 6.0 cm.
3. Tumor distance from pleural surface: 0.1 cm.

Lymph Node Status:

1. One peribronchial lymph node negative for malignancy.
2. See parts B, C.

Other:

1. pTNM stage: pT2b, N0.

B. Level 9 lymph nodes, excision:

Four lymph nodes, negative for metastatic disease.

C. Level 7 lymph nodes, excision:

One lymph node, negative for metastatic disease.

TIPTA Discrepancy		

Electronic Signature:

COMMENTS:

Current I practice guidelines recommend determination of EGFR and KRAS mutation status in adenocarcinoma of lung to help select patients for Tyrosine-Kinase Inhibitor (TKI) therapy. EGFR-activating mutations have been shown to be significantly associated with response to TKIs and KRAS mutations are associated with TKI resistance. They are mutually exclusive. Additionally, recent data show that ALK (Anaplastic Lymphoma Kinase) gene rearrangements in adenocarcinoma of lung are associated with resistance to TKIs and have favorable response rates to Crizotinib, the ALK inhibitor agent currently in clinical trials. Mutation analysis for KRAS and EGFR-TK domain and ALK gene rearrangement by FISH is available as the testing may be performed on paraffin-embedded tissue from the primary or metastatic tumor or pleural fluid cell block. These tests are available on request as a panel or as individual assays.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: year old male with right lower lobe lung cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Right lower lobe
- B. Level 9 lymph node
- C. Level 7 lymph node

GROSS DESCRIPTION:

- A. The first container A is received in formalin labeled right lower lobe. The specimen consists of a lower lobe lobectomy specimen measuring 16.0 x 14.0 x 6.0 cm and weighs 317 grams. The pleural surface is brown tan shaggy slightly anthracotic. The pleural surface has been inked. Sectioning reveals a yellow gray fibrous stringy lesion measuring 6.0 x 5.0 x 3.5 cm that is 0.1 cm of the pleural surface and comes within 4.5 cm of the bronchial margin and 6.0 cm of the stapled edge. The stringy portions display cystic spaces. There is a firm fibrous area within the lesion at the periphery measuring 4.5 cm. The surrounding lung tissue is red tan spongy and congested. Within the peribronchial soft tissue there is a gray anthracotic nodule consistent with lymph node measuring 1.0 cm. Received with the specimen are three cassettes, one green, one yellow and one blue, labeled Representative sections are submitted in cassettes labeled: sections from the stapled edge--6; bronchial and vascular margin--7; sections from normal surrounding lung and peribronchial lymph node--8.
- B. The second container B is received in formalin labeled level 9 lymph node. The specimen consists of a piece of brown tan soft tissue, 5.0 x 2.0 x 2.0 cm. Sectioning reveals four brown tan nodules consistent with lymph nodes measuring from 1.1 to 2. The largest lymph node is calcified. The calcified node is decalcified and the lymph nodes are entirely submitted in cassettes labeled as follows: two probable nodes each bisected--1; one probable node sectioned--2 to 4; the largest lymph node submitted after decalcification--5 and 6.
- C. The third container C is received in formalin labeled level 7 lymph node. The specimen consists of a brown tan nodule consistent with lymph node measuring 1.5 x 1.0 x 0.5 cm. The lymph node is bisected and entirely submitted in a single cassette labeled as follows: two

Source: NCI Genomic Data Commons file 4f4c3c62-cf38-4140-b3c3-54563afdf1d7 (TCGA-56-A4BX.921CAB89-9289-4C98-9746-4BFB3569E338.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).